Gene-level copy-number profile of tumor specimen HTMCP-01-06-00036-01E from CGCI case HTMCP-01-06-00036, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen HTMCP-01-06-00036-01E: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1a13521-f14e-43fe-ad67-da17f3a19873.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00036-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/124bbcaf-c6b9-45a3-83e2-c3bae636795a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 164; copy number 2: 2,262; copy number 3: 13,032; copy number 4: 33,232; copy number 5: 8,063; copy number 6: 1,489; copy number 7: 52; copy number 8: 101.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 164. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
